Surgical pathology report (de-identified scan), TCGA case TCGA-NG-A4VU, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Roswell Park, specimen TCGA-NG-A4VU-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinosarcoma
Mixed Mullerian Tumor, malignant
8950/3

Site: Endometrium C54.1

9/22/13

SPECIMENS:

- A. OMENTUM
- B. OMENTUM
- C. UTERUS, LEFT TUBE AND OVARY
- D. RIGHT TUBE AND OVARY
- E. TUMOR ON BLADDER PERITONEUM

SPECIMEN(S):

- A. OMENTUM
- B. OMENTUM
- C. UTERUS, LEFT TUBE AND OVARY
- D. RIGHT TUBE AND OVARY
- E. TUMOR ON BLADDER PERITONEUM

DIAGNOSIS:

- A. OMENTUM:
- METASTATIC HIGH GRADE SEROUS CARCINOMA COMPONENT, SEE NOTE:
- B. OMENTUM:
- METASTATIC HIGH GRADE SEROUS CARCINOMA COMPONENT, SEE NOTE:
- C. UTERUS, LEFT TUBE AND OVARY:
- MALIGNANT MIXED MÜLLERIAN TUMOR (11 CM), ARISING IN ENDOMETRIUM AND WITH LESS THAN 50% DEPTH OF MYOMETRIAL INVASION WITH NECROSIS. SEE NOTE.
- UTERINE SEROSA AND PARA-TUBAL/PARA-OVARIAN SOFT TISSUE WITH METASTATIC EPITHELIAL COMPONENT (HIGH GRADE PAPILLARY SEROUS CARCINOMA) OF THE TUMOR
- LYMPHOVASCULAR INVASION IS IDENTIFIED.
- UTERINE ANGIOMYOLIPOMA (1.4 CM)
- THE UNINVOLVED ENDOMETRIUM SHOWS FOCALLY CYSTIC ATROPHY
- SEE SYNOPTIC REPORT
- D. TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:
- PARA-TUBAL/PARA-OVARIAN SOFT TISSUE WITH METASTATIC HIGH GRADE SEROUS CARCINOMA COMPONENT
- E. TUMOR ON BLADDER PERITONEUM:
- METASTATIC HIGH GRADE SEROUS CARCINOMA COMPONENT.

Note: The largely polypoid tumor arises in the endometrium, with superficial myometrial invasion. The malignant stroma is heterologous with prominent rhabdomyosarcomatous component. The malignant epithelial component is mainly a high grade serous carcinoma.

SYNOPTIC REPORT - ENDOMETRIUM

Specimens Involved

Specimens: A: OMENTUM

B: OMENTUM

C: UTERUS, LEFT TUBE AND OVARY

D: RIGHT TUBE AND OVARY

E: TUMOR ON BLADDER PERITONEUM

Prior biopsy specimen: Yes

Prior case #:

Prior biopsy diagnosis: MALIGNANT MIXED MESODERMAL TUMOR WITH PROMINENT RHABDOMYOSARCOMATOUS DIFFERENTIATION

Specimen Type: uterus, cervix, bilateral adnexa, omentum, bladder peritoneum

Tumor Size: Greatest dimension: 11cm

Additional dimensions: 9.5cm x 7.5cm

WHO CLASSIFICATION

Carcinosarcoma (malignant Mullerian mixed tumor; metaplastic carcinoma) 8980/3

[page 2 of 2]
Histologic Grade: high grade MMMT
Myometrial Invasion: Invasion present
Depth of invasion: 2mm
Myometrial thickness: 19mm
Venous/lymphatic invasion: Present
Cervical Involvement: No
Margins: Cannot be assessed
Lymph nodes: No lymph nodes sampled
Other tissue removed for staging: Omentum and urinary bladder peritoneum
Other positive sites: Omentum and urinary bladder peritoneum
Additional Findings: Uterine angiomylipoma
Peritoneal cytology: Positive
Cytology case #:
Pathologic stage (pTNM): pT 3b N x M x

GROSS DESCRIPTION:

A. OMENTUM

Received fresh labeled with the patient's identification and 'omentum' is a tan pink-grey firm segment of omentum 2.5 x 2 x 0.6cm. The specimen is serially sectioned. A portion of the specimen is submitted for tissue procurement. The remainder of the specimen is submitted in A1.

B. OMENTUM

Received in formalin labeled with the patient's identification and 'omentum' is a tan yellow segment of omentum 8.5 x 4 x 3cm. The specimen is serially sectioned to reveal a tan white firm cut surface. Representatively submitted in B1-B3.

C. UTERUS, LEFT TUBE AND OVARY

Received fresh is a 412g supracervical hysterectomy specimen with attached left tube and ovary. The uterus is 12cm from fundus to lower uterine segment, 11cm from cornua to cornua and 8.3cm from anterior to posterior. The serosa is tan pink and smooth. The specimen is bivalved into anterior and posterior halves to reveal a tan pink friable mass 11 x 9.5 x 7.5cm, occupying 100% of the cavity and attached to the posterior aspect of the specimen. The mass grossly appear to be confined to the endometrium. The uninvolved endometrium is 0.1cm. The uninvolved trabeculated myometrium is 2.3cm and remarkable for a 1.4 x 1.3 x 1cm tan white firm well circumscribed mass. The mass is sectioned to reveal a homogenous white whorled cut surface without areas of hemorrhage or necrosis. The attached left tan pink cerebriform ovary is 1.3 x 0.9 x 0.7cm, is bivalved to reveal unremarkable parenchyma. The attached left fimbriated fallopian tube is 4cm in length x 1cm in diameter. The fallopian tube is serially sectioned to reveal a patent lumen. A portion of the specimen is submitted for tissue procurement. Gross photographs are taken. Representatively submitted as follows:

C1-C2: anterior lower uterine segment

C3-C4: posterior lower uterine segment

C5-C6: anterior endomyometrium

C7: anterior mass

C8-C10: posterior endomyometrium where mass is attached

C11: left ovary

C12: left fallopian tube

D. RIGHT TUBE AND OVARY

Received in formalin labeled with the patient's identification and 'right tube and ovary' is a 3g tan pink cerebriform ovary 2.3 x 1.6 x 0.6cm with attached fimbriated fallopian tube 4 x 1.2cm. The ovary is bivalved to reveal unremarkable parenchyma. The fallopian tube is serially sectioned to reveal a patent lumen. Entirely submitted:

D1: right ovary

D2-D3: right fallopian tube

E. TUMOR ON BLADDER PERITONEUM

Received in formalin labeled with the patient's identification and 'tumor on bladder peritoneum' is a 11 x 9 x 3.5cm firm tan white tissue fragment. The specimen is serially sectioned to reveal a homogenous yellow white cut surface. Representatively submitted in E1-E2.

CLINICAL HISTORY:

year old

female

with uterine carcinoma on endometrial biopsy.

PRE-OPERATIVE DIAGNOSIS:

Uterine cancer

HI/PA Discrepancy		✓

Source: NCI Genomic Data Commons file 1f5dbc19-978c-4834-904f-bc084d65d9be (TCGA-NG-A4VU.F9FF5984-7961-4B52-B649-D074BC0FFA44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).